Somatic mutation profile of tumor specimen TCGA-XF-A8HB-01A (aliquot TCGA-XF-A8HB-01A-11D-A364-08) from TCGA case TCGA-XF-A8HB, project TCGA-BLCA (Bladder Urothelial Carcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Papillary transitional cell carcinoma; Tissue or organ of origin: Bladder, NOS; AJCC pathologic stage: Stage II; Tumor grade: High Grade; Age at diagnosis: 50.8 years (18,544 days).
Specimen TCGA-XF-A8HB-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 7292e0df-0f22-4acb-80c9-04c7c9b2590b.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-XF-A8HB-10A (Blood Derived Normal), aliquot TCGA-XF-A8HB-10A-01D-A362-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/34150e43-3925-4127-b9dc-5f8d0646d0b9

The open-access MAF lists 78 somatic variants for this specimen: 62 protein-altering or splice-affecting, 14 silent, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 57, Silent 14, Frame Shift Del 2, Splice Site 2, RNA 1, Nonsense Mutation 1, Intron 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- NRAS | c.182A>G p.Q61R | Missense Mutation (SNP) | VAF 52/108 reads (48%) | hotspot (GDC flag); SIFT tolerated (0.06); PolyPhen benign (0.251); catalogued as rs11554290, COSV54736340, COSV54736624, COSV54738969, COSV54747786; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- ADGRB3 | c.686G>T p.C229F | Missense Mutation (SNP) | VAF 14/57 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.962); catalogued as rs1308443705, COSV65403763; called by muse, mutect2, varscan2
- ANK2 | c.4300C>A p.P1434T | Missense Mutation (SNP) | VAF 28/63 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV52170513; called by muse, mutect2, varscan2
- APC | c.6235G>C p.D2079H | Missense Mutation (SNP) | VAF 17/77 reads (22%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.997); catalogued as COSV57356056, COSV57384156; called by muse, mutect2, varscan2
- ARIH1 | c.1087C>T p.R363C | Missense Mutation (SNP) | VAF 33/78 reads (42%) | SIFT deleterious (0.02); PolyPhen benign (0.091); catalogued as COSV65912105; called by muse, mutect2, varscan2
- BMPR1B | c.263A>G p.H88R | Missense Mutation (SNP) | VAF 7/103 reads (7%) | SIFT tolerated (0.27); PolyPhen benign (0.001); catalogued as COSV99215290; called by muse, mutect2
- CCNB2 | c.829G>A p.G277R | Missense Mutation (SNP) | VAF 66/141 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.942); catalogued as rs373918972; called by muse, mutect2, varscan2
- CD274 | c.245G>A p.R82K | Missense Mutation (SNP) | VAF 18/38 reads (47%) | SIFT tolerated (0.39); PolyPhen benign (0.219); catalogued as COSV67501446; called by muse, mutect2, varscan2
- CHST4 | c.478C>T p.P160S | Missense Mutation (SNP) | VAF 20/50 reads (40%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.456); catalogued as COSV58297584; called by muse, mutect2, varscan2
- CMKLR1 | c.166C>A p.L56M (on ENST00000312143 / NM_001142344.2; = p.L54M on NM_004072.3) | Missense Mutation (SNP) | VAF 25/51 reads (49%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.527); catalogued as COSV56439456, COSV56441754; called by muse, mutect2, varscan2
- COG3 | c.352C>G p.Q118E | Missense Mutation (SNP) | VAF 24/56 reads (43%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as COSV63073721; called by muse, mutect2, varscan2
- COL4A5 | c.4039G>A p.E1347K | Missense Mutation (SNP) | VAF 37/85 reads (44%) | SIFT tolerated (0.68); PolyPhen benign (0); catalogued as COSV100087501, COSV60364857; called by muse, mutect2, varscan2
- CS | c.766C>T p.R256C | Missense Mutation (SNP) | VAF 20/51 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV60832262; called by muse, mutect2, varscan2
- CS | c.351G>T p.E117D | Missense Mutation (SNP) | VAF 31/66 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV60833855; called by muse, mutect2, varscan2
- CTTNBP2 | c.2030G>C p.R677T | Missense Mutation (SNP) | VAF 42/90 reads (47%) | SIFT tolerated (0.16); PolyPhen benign (0.05); catalogued as rs1255017790, COSV50415788; called by muse, mutect2, varscan2
- DCAF6 | c.248G>A p.R83K | Missense Mutation (SNP) | VAF 49/100 reads (49%) | SIFT tolerated (0.61); PolyPhen benign (0.003); catalogued as COSV56580797; called by muse, mutect2, varscan2
- DCTN1 | c.1629G>C p.E543D | Missense Mutation (SNP) | VAF 21/48 reads (44%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.983); catalogued as COSV62620843; called by muse, mutect2, varscan2
- DENND1C | c.490C>A p.P164T | Missense Mutation (SNP) | VAF 16/31 reads (52%) | SIFT tolerated (0.08); PolyPhen benign (0.033); catalogued as rs571498088, COSV67373873; called by muse, mutect2, varscan2
- DNAH9 | c.9187A>C p.K3063Q | Missense Mutation (SNP) | VAF 14/30 reads (47%) | SIFT tolerated (0.7); PolyPhen benign (0); catalogued as COSV52358017; called by muse, mutect2, varscan2
- ELP4 | c.1067G>A p.R356Q (on ENST00000350638; = p.R355Q on NM_019040.5) | Missense Mutation (SNP) | VAF 21/48 reads (44%) | SIFT tolerated (0.12); PolyPhen benign (0.062); catalogued as rs376061277, COSV63357332; called by muse, mutect2, varscan2
- EPB41L5 | c.1282G>C p.V428L | Missense Mutation (SNP) | VAF 16/27 reads (59%) | SIFT tolerated (0.15); PolyPhen benign (0.003); catalogued as COSV55353999; called by muse, mutect2, varscan2
- EPB42 | c.580C>T p.R194C (on ENST00000441366 / NM_001114134.2; = p.R224C on NM_000119.3) | Missense Mutation (SNP) | VAF 19/50 reads (38%) | SIFT deleterious (0.04); PolyPhen benign (0.003); catalogued as rs139182437; called by muse, mutect2, varscan2
- FAT3 | c.1207G>C p.E403Q | Missense Mutation (SNP) | VAF 14/26 reads (54%) | SIFT tolerated (0.42); PolyPhen possibly damaging (0.891); catalogued as COSV53133720; called by muse, mutect2, varscan2
- FCMR | c.671C>T p.T224M | Missense Mutation (SNP) | VAF 25/58 reads (43%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.869); catalogued as rs748391555, COSV65567716; called by muse, mutect2, varscan2
- HLA-E | c.892G>A p.A298T | Missense Mutation (SNP) | VAF 48/53 reads (91%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.039); catalogued as COSV64927630; called by muse, mutect2, varscan2
- HSP90AA1 | c.196G>T p.D66Y | Missense Mutation (SNP) | VAF 31/111 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs747407643, COSV53489609; called by muse, mutect2, varscan2
- IGHG3 | c.686C>T p.T229M | Missense Mutation (SNP) | VAF 104/342 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs587733341; called by muse, mutect2, varscan2
- ITIH6 | c.2773G>A p.E925K | Missense Mutation (SNP) | VAF 17/33 reads (52%) | SIFT tolerated (0.15); PolyPhen benign (0.078); catalogued as COSV54490779; called by muse, mutect2, varscan2
- KCNU1 | c.204C>A p.F68L | Missense Mutation (SNP) | VAF 9/35 reads (26%) | SIFT tolerated (0.53); PolyPhen benign (0); catalogued as COSV67757467; called by muse, mutect2, varscan2
- KIR3DL3 | c.1055-1G>T p.X352_splice | Splice Site (SNP) | VAF 87/146 reads (60%) | catalogued as rs770908274, COSV99399674; called by muse, mutect2, varscan2
- KSR1 | c.2311G>A p.E771K (on ENST00000644974 / NM_001367810.1; = p.E656K on NM_014238.2) | Missense Mutation (SNP) | VAF 31/68 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs1261408043, COSV52034969; called by muse, mutect2, varscan2
- LCE2D | c.319G>A p.G107R | Missense Mutation (SNP) | VAF 12/85 reads (14%) | SIFT tolerated, low confidence (0.17); PolyPhen benign (0.009); catalogued as COSV64229083; called by muse, mutect2, varscan2
- MUC5B | c.11456T>G p.M3819R | Missense Mutation (SNP) | VAF 53/157 reads (34%) | SIFT tolerated (0.44); PolyPhen benign (0); catalogued as COSV71593691; called by muse, mutect2, varscan2
- MVB12A | c.814G>A p.V272I | Missense Mutation (SNP) | VAF 37/88 reads (42%) | SIFT tolerated (0.64); PolyPhen benign (0.051); catalogued as rs374591131; called by muse, mutect2, varscan2
- MYH1 | c.3815G>A p.R1272Q | Missense Mutation (SNP) | VAF 35/94 reads (37%) | SIFT tolerated (0.16); PolyPhen benign (0.202); catalogued as rs554558885, COSV56851561; called by muse, mutect2, varscan2
- MYT1L | c.734G>A p.R245Q | Missense Mutation (SNP) | VAF 36/75 reads (48%) | SIFT tolerated, low confidence (0.29); PolyPhen benign (0.015); catalogued as rs771189602, COSV67722354, COSV67725374; called by muse, mutect2, varscan2
- NALCN | c.1050G>A p.M350I | Missense Mutation (SNP) | VAF 18/37 reads (49%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as COSV99212819; called by muse, mutect2, varscan2
- NEB | c.11536T>C p.W3846R | Missense Mutation (SNP) | VAF 46/124 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV51430102; called by muse, mutect2, varscan2
- OR11G2 | c.544C>A p.L182I | Missense Mutation (SNP) | VAF 46/91 reads (51%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.988); catalogued as COSV62132390; called by muse, mutect2, varscan2
- OR4K15 | c.989T>C p.L330P (on ENST00000305051; = p.L306P on NM_001005486.1) | Missense Mutation (SNP) | VAF 21/48 reads (44%) | SIFT deleterious (0.02); PolyPhen benign (0.021); catalogued as COSV59301963; called by muse, mutect2, varscan2
- OR6K3 | c.827G>A p.R276H (on ENST00000368146; = p.R260H on NM_001005327.2) | Missense Mutation (SNP) | VAF 23/60 reads (38%) | SIFT deleterious (0.05); PolyPhen benign (0.344); catalogued as rs145239299; called by muse, mutect2, varscan2
- PCGF5 | c.668G>A p.R223Q | Missense Mutation (SNP) | VAF 33/67 reads (49%) | SIFT tolerated (0.33); PolyPhen benign (0); catalogued as rs755316155, COSV60237330, COSV60237907; called by muse, mutect2, varscan2
- POLR3G | c.26G>A p.R9H | Missense Mutation (SNP) | VAF 50/102 reads (49%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.601); catalogued as rs780251585, COSV67625629; called by muse, mutect2, varscan2
- PRAM1 | c.1409G>A p.R470Q | Missense Mutation (SNP) | VAF 5/11 reads (45%) | SIFT tolerated (0.22); PolyPhen benign (0.023); catalogued as rs1416092875, COSV99725171; called by muse, mutect2
- PROS1 | c.966-1G>C p.X322_splice | Splice Site (SNP) | VAF 5/23 reads (22%) | catalogued as CS163632, COSV101260224, COSV101260680; called by muse, mutect2
- RIMS1 | c.2887G>A p.G963R | Missense Mutation (SNP) | VAF 14/52 reads (27%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.972); catalogued as rs371034073; called by muse, mutect2, varscan2
- RIMS2 | c.4586G>A p.R1529H (on ENST00000666250 / NM_001348490.2; = p.R1100H on NM_014677.5 and 7 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 29/186 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs200286153, COSV51695461; called by muse, mutect2, varscan2
- RNF26 | c.811C>T p.R271* | Nonsense Mutation (SNP) | VAF 17/39 reads (44%) | catalogued as rs370172683; called by muse, mutect2, varscan2
- ROS1 | c.4552G>C p.E1518Q | Missense Mutation (SNP) | VAF 8/29 reads (28%) | SIFT tolerated (0.18); PolyPhen benign (0.147); catalogued as COSV63857051; called by muse, mutect2, varscan2
- RYR2 | c.11267C>T p.A3756V | Missense Mutation (SNP) | VAF 21/39 reads (54%) | SIFT tolerated (0.44); PolyPhen benign (0.039); catalogued as COSV63694438; called by muse, mutect2, varscan2
- SH3PXD2A | c.1555C>T p.R519W (on ENST00000369774 / NM_001365079.1; = p.R491W on NM_014631.2) | Missense Mutation (SNP) | VAF 32/66 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV100280177, COSV60118315; called by muse, mutect2, varscan2
- SPG11 | c.2737C>A p.Q913K | Missense Mutation (SNP) | VAF 28/59 reads (47%) | SIFT tolerated (0.46); PolyPhen benign (0.014); catalogued as COSV55997751, COSV55999873; called by muse, mutect2, varscan2
- SSH3 | c.431C>T p.T144M | Missense Mutation (SNP) | VAF 13/32 reads (41%) | SIFT tolerated (0.14); PolyPhen benign (0.075); catalogued as rs778087544, COSV57384470; called by muse, mutect2, varscan2
- TEP1 | c.3242G>C p.G1081A | Missense Mutation (SNP) | VAF 58/130 reads (45%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.909); catalogued as COSV52995045; called by muse, mutect2, varscan2
- TMEM245 | c.1400T>C p.F467S | Missense Mutation (SNP) | VAF 56/118 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV65823395, COSV65823411; called by muse, mutect2, varscan2
- UNC5B | c.2188C>G p.L730V | Missense Mutation (SNP) | VAF 7/20 reads (35%) | SIFT tolerated (0.15); PolyPhen benign (0.001); catalogued as COSV58978317; called by muse, mutect2, varscan2
- ZFR2 | c.1888G>A p.E630K | Missense Mutation (SNP) | VAF 12/13 reads (92%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.727); catalogued as rs575924514, COSV53596371, COSV53602679; called by muse, mutect2, varscan2
- ZMAT1 | c.787C>T p.P263S | Missense Mutation (SNP) | VAF 66/145 reads (46%) | SIFT tolerated (0.32); PolyPhen benign (0.013); catalogued as rs1367848855, COSV65659130; called by muse, mutect2, varscan2
- ZNF236 | c.4817C>T p.S1606L | Missense Mutation (SNP) | VAF 31/71 reads (44%) | SIFT deleterious (0.01); PolyPhen benign (0.057); catalogued as rs748399601, COSV53491213; called by muse, mutect2, varscan2
- ZNF276 | c.1793C>T p.P598L (on ENST00000443381 / NM_001113525.2; = p.P523L on NM_152287.4) | Missense Mutation (SNP) | VAF 11/18 reads (61%) | SIFT tolerated (0.36); PolyPhen benign (0); catalogued as rs752058479, COSV99234520; called by muse, varscan2
- NHLRC4 | c.105del p.Q35Hfs*38 | Frame Shift Del (DEL) | VAF 6/21 reads (29%) | called by mutect2, varscan2
- XIRP1 | c.2475_2487del p.E826Sfs*31 | Frame Shift Del (DEL) | VAF 4/30 reads (13%) | called by mutect2, pindel
- AMPH | c.243G>A p.L81= | Silent (SNP) | VAF 28/56 reads (50%) | catalogued as COSV57747369; called by muse, mutect2, varscan2
- ARID1B | c.4620G>A p.A1540= | Silent (SNP) | VAF 36/39 reads (92%) | catalogued as rs776881575, COSV51668274; ClinVar: likely benign; called by muse, mutect2, varscan2
- CCNT1 | c.384A>G p.Q128= | Silent (SNP) | VAF 23/45 reads (51%) | catalogued as COSV56064894; called by muse, mutect2, varscan2
- CDH9 | c.1818C>T p.I606= | Silent (SNP) | VAF 10/25 reads (40%) | catalogued as COSV50318599; called by muse, mutect2, varscan2
- IL11RA | c.306G>A p.G102= | Silent (SNP) | VAF 8/22 reads (36%) | catalogued as rs979295919, COSV58840840; called by muse, mutect2, varscan2
- MCAM | c.495C>T p.N165= | Silent (SNP) | VAF 18/41 reads (44%) | catalogued as rs374366046; called by muse, mutect2, varscan2
- MYCBP2 | c.8154G>A p.K2718= (on ENST00000357337; = p.K2756= on NM_015057.5) | Silent (SNP) | VAF 62/127 reads (49%) | catalogued as COSV62008897, COSV62026685; called by muse, mutect2, varscan2
- PIGT | c.369G>C p.V123= | Silent (SNP) | VAF 45/69 reads (65%) | catalogued as COSV54127182; called by muse, mutect2, varscan2
- SALL3 | c.2250C>T p.N750= | Silent (SNP) | VAF 17/34 reads (50%) | catalogued as rs932625576, COSV73306189; called by muse, mutect2, varscan2
- TDO2 | c.1185T>C p.C395= | Silent (SNP) | VAF 34/38 reads (89%) | catalogued as COSV70809352; called by muse, mutect2, varscan2
- TNKS2 | c.3210A>G p.Q1070= | Silent (SNP) | VAF 42/85 reads (49%) | catalogued as rs759381857, COSV65415973; called by muse, mutect2, varscan2
- TTBK2 | c.588C>T p.N196= | Silent (SNP) | VAF 20/43 reads (47%) | catalogued as rs531094726, COSV51158327; ClinVar: likely benign; called by muse, varscan2
- WNK1 | c.5568G>A p.K1856= (on ENST00000315939 / NM_018979.4; = p.K1608= on NM_014823.3) | Silent (SNP) | VAF 30/68 reads (44%) | catalogued as COSV60037553; called by muse, mutect2, varscan2
- ZNF628 | c.1728G>A p.A576= | Silent (SNP) | VAF 10/38 reads (26%) | catalogued as rs1349983714, COSV52700553; called by muse, mutect2, varscan2
- AL136982.4 | n.954C>T | RNA (SNP) | VAF 72/150 reads (48%) | catalogued as rs770042879; called by muse, mutect2, varscan2
- BAX | c.474+185C>G | Intron (SNP) | VAF 6/59 reads (10%) | catalogued as COSV99508937; called by muse, mutect2
